Somatic mutation profile of tumor specimen TCGA-HT-8011-01A (aliquot TCGA-HT-8011-01A-11D-2395-08) from TCGA case TCGA-HT-8011, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 55.2 years (20,175 days).
Specimen TCGA-HT-8011-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 42ddddf8-e4cd-4982-b9a1-212c14eab072.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-8011-10A (Blood Derived Normal), aliquot TCGA-HT-8011-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0b508127-5964-4397-8fde-4867375afe0d

The open-access MAF lists 39 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 9, Nonsense Mutation 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STAG2 | c.646C>T p.R216* | Nonsense Mutation (SNP) | VAF 46/62 reads (74%) | hotspot (GDC flag); catalogued as COSV54350685, COSV54365974; called by muse, mutect2, varscan2
- TCF12 | c.1419dup p.V474Cfs*12 | Frame Shift Ins (INS) | VAF 6/15 reads (40%) | catalogued as rs886037637, CI131568; ClinVar: pathogenic; called by mutect2, varscan2
- ACE | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs374910265; called by muse, mutect2, varscan2
- AGL | c.3289C>T p.R1097C | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768133891, COSV54057814; called by muse, mutect2, varscan2
- BTC | c.479C>A p.T160N | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.027); catalogued as COSV104430735, COSV67548026; called by muse, mutect2, varscan2
- CREBBP | c.1847del p.P616Lfs*6 | Frame Shift Del (DEL) | VAF 39/127 reads (31%) | catalogued as COSV52143307; called by mutect2, pindel, varscan2
- CRTC1 | c.1846C>A p.P616T | Missense Mutation (SNP) | VAF 183/503 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58722967, COSV58723751; called by muse, mutect2, varscan2
- CSN3 | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV59244918; called by muse, mutect2, varscan2
- DLC1 | c.2009G>C p.R670P (on ENST00000276297 / NM_001348081.2; = p.R233P on NM_006094.5) | Missense Mutation (SNP) | VAF 110/203 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52325325; called by muse, mutect2, varscan2
- DSG3 | c.286C>A p.P96T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57129285; called by muse, mutect2, varscan2
- FAT2 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201874812, COSV55828205; called by muse, mutect2, varscan2
- HS3ST3A1 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs1392165592, COSV99404437; called by muse, mutect2, varscan2
- LILRB2 | c.1588G>T p.E530* | Nonsense Mutation (SNP) | VAF 18/137 reads (13%) | catalogued as COSV58748047; called by muse, mutect2, varscan2
- LTBP2 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.244); catalogued as rs757872088, COSV56213484; called by muse, mutect2
- NFAT5 | c.1142+1G>A p.X381_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV63025519; called by muse, varscan2
- OR2M7 | c.85T>A p.F29I | Missense Mutation (SNP) | VAF 112/245 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.045); catalogued as COSV58740471; called by muse, mutect2, varscan2
- OR4N2 | c.238C>T p.R80W | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs201593869; called by muse, mutect2, varscan2
- OR5M1 | c.316G>A p.A106T | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.012); catalogued as rs752210753, COSV73202241; called by muse, mutect2, varscan2
- PLD1 | c.2749C>T p.R917C | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774502670, COSV60573445; called by muse, mutect2, varscan2
- QDPR | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV55551643; called by muse, mutect2, varscan2
- QPCT | c.623C>G p.S208C | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV58121111; called by muse, mutect2, varscan2
- RAP1GDS1 | c.508G>A p.D170N (on ENST00000408927 / NM_001100427.2; = p.D171N on NM_021159.5) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.989); catalogued as rs980227479, COSV52791336, COSV99217315; called by muse, mutect2, varscan2
- RRAGA | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 17/26 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65844084; called by muse, mutect2, varscan2
- RUSC2 | c.3734A>T p.E1245V | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.092); catalogued as COSV63430220; called by muse, mutect2, varscan2
- SPEF2 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV61552935; called by muse, mutect2, varscan2
- TECRL | c.542C>A p.P181Q | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.467); catalogued as COSV101168616, COSV67087739, COSV67087908; called by muse, mutect2, varscan2
- TMEM229B | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as rs896368785, COSV62539097; called by muse, mutect2, varscan2
- TUBA3C | c.331G>A p.G111S | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.986); catalogued as rs140107190; called by muse, mutect2, varscan2
- ZNF681 | c.1622A>T p.K541I | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV68075498; called by muse, mutect2, varscan2
- CCDC170 | c.1377C>T p.D459= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs113968720, COSV53347391; called by muse, mutect2, varscan2
- COBL | c.1740G>A p.A580= | Silent (SNP) | VAF 19/82 reads (23%) | catalogued as rs746473868, COSV54355606, COSV54356670; called by muse, mutect2, varscan2
- COL6A3 | c.8415C>T p.N2805= | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as rs375442243; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- EMC1 | c.1224G>A p.Q408= | Silent (SNP) | VAF 44/129 reads (34%) | catalogued as COSV64346548; called by muse, mutect2, varscan2
- ESRRB | c.192C>T p.G64= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as rs757302943, COSV55060289; called by muse, mutect2, varscan2
- HS3ST6 | c.480G>A p.T160= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as rs767463038, COSV53536670; called by muse, mutect2, varscan2
- LILRB2 | c.1776C>T p.Y592= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as rs756088691, COSV58748040; called by muse, mutect2, varscan2
- TEF | c.816C>T p.N272= | Silent (SNP) | VAF 57/143 reads (40%) | catalogued as COSV56748840; called by muse, mutect2, varscan2
- ZNF560 | c.1347A>T p.G449= | Silent (SNP) | VAF 42/91 reads (46%) | catalogued as COSV56867271, COSV56871146; called by muse, mutect2, varscan2
- TMEM99 | n.588T>A | RNA (SNP) | VAF 85/182 reads (47%) | catalogued as COSV56985258; called by muse, mutect2, varscan2
